HCMI case HCM-CSHL-0740-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aa0d437f-845b-43af-98e9-c7e5c3b55d33

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1949; Vital status: Dead; Days to death: 1,318 days (3.6 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.2; Tissue or organ of origin: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 66.8 years (24,398 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IVA; AJCC pathologic T: T4a; AJCC pathologic N: N2a; AJCC pathologic M: M1a; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Liver.
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 17 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFOX; Days to treatment start: 70 days; Days to treatment end: 245 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 343 days; Days to treatment end: 706 days (1.9 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 593 days (1.6 years); Days to treatment end: 791 days (2.2 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 714 days (2.0 years); Days to treatment end: 791 days (2.2 years).
   Treatment given: Treatment type: Radiation, 3D Conformal; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 969 days (2.7 years); Days to treatment end: 984 days (2.7 years).
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 1,218 days (3.3 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C79.8; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Pelvis, NOS; Classification of tumor: metastasis; Age at diagnosis: 66.8 years (24,398 days).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Bevacizumab; Treatment intent type: Maintenance Therapy; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFOX; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Irinotecan; Treatment intent type: Maintenance Therapy; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Oxaliplatin; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFOX; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Xeloda; Treatment intent type: Maintenance Therapy; Treatment outcome: Progressive Disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 1,278 days (3.5 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 1,243.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- CEA: 361 ng/mL.
- CEA: 617 ng/mL.
- KRAS mutation, nos: Positive; Amino-acid change: p.Gly13Asp.
- MLH1 (IHC): Negative.
- MSH2 (IHC): Negative.
- MSH6 (IHC): Negative.
- PMS2 (IHC): Negative.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 60.8 kg; Height: 162.6 cm; BMI: 23.
- Timepoint category: Prior to Diagnosis; Risk factors: Diverticulosis.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0740-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0740-C18-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 20; Percent tumor nuclei: 50; Percent normal cells: 5; Percent necrosis: 60; Percent stromal cells: 15; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 3.
  Slide HCM-CSHL-0740-C18-06A-01-S1-HE: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 50; Percent normal cells: 15; Percent necrosis: 10; Percent stromal cells: 35; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
- Sample HCM-CSHL-0740-C18-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0740-C18-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
